Somatic mutation profile of tumor specimen TCGA-NH-A6GB-01A (aliquot TCGA-NH-A6GB-01A-11D-A36X-10) from TCGA case TCGA-NH-A6GB, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.5 years (26,100 days).
Specimen TCGA-NH-A6GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bf1bb0f-743a-4431-813c-76e4c95303ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A6GB-10A (Blood Derived Normal), aliquot TCGA-NH-A6GB-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/142086de-33b7-4ded-bc7d-1892c2fafe74

The open-access MAF lists 174 somatic variants for this specimen: 127 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 44, Nonsense Mutation 6, Frame Shift Del 4, Splice Site 3, RNA 2, Frame Shift Ins 2, Nonstop Mutation 1, In Frame Del 1, Intron 1, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 91/254 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as COSV55298165; called by muse, mutect2, varscan2
- ABCA8 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 137/268 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs571544554, COSV99287169; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 137/409 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs201627097, CM121484, COSV55029221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACKR1 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100929704; called by muse, mutect2, varscan2
- ACP7 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100488646; called by muse, mutect2, varscan2
- AL031777.2 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs201905916, COSV61911571; called by muse, mutect2, varscan2
- AL133500.1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious, low confidence (0); catalogued as COSV99860513; called by muse, mutect2, varscan2
- AMOTL1 | c.2322G>C p.Q774H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100504830; called by muse, mutect2, varscan2
- ARAF | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs773318953, COSV99283500; called by muse, mutect2, varscan2
- ATP2C1 | c.382_383del p.L128* | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | catalogued as rs866727395; called by pindel, varscan2
- ATP5MPL | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.04); catalogued as rs749080256, COSV99744070; called by muse, mutect2, varscan2
- BCO2 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as rs1222276826, COSV100730258; called by muse, mutect2
- BGN | c.351C>T p.Y117= | Splice Region (SNP) | VAF 65/124 reads (52%) | catalogued as rs782268995, COSV100525343; called by muse, mutect2, varscan2
- BOLL | c.852A>T p.*284Yext*11 | Nonstop Mutation (SNP) | VAF 39/220 reads (18%) | catalogued as COSV99987511; called by muse, mutect2, varscan2
- C2orf88 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777387815, COSV61409696; called by muse, mutect2, varscan2
- CAMTA1 | c.2922G>T p.Q974H | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57884034; called by muse, mutect2, varscan2
- CCDC172 | c.111_112insC p.I38Hfs*2 | Frame Shift Ins (INS) | VAF 40/144 reads (28%) | catalogued as COSV100320055; called by mutect2, pindel, varscan2
- CCNK | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as COSV101110548; called by muse, mutect2, varscan2
- CD86 | c.279G>A p.W93* (on ENST00000330540 / NM_175862.5; = p.W87* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 28/140 reads (20%) | catalogued as COSV100054264; called by muse, mutect2, varscan2
- CD93 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55666316; called by muse, mutect2, varscan2
- CDH22 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs149967017; called by muse, mutect2, varscan2
- CDYL2 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768656038, COSV101629636; called by muse, mutect2, varscan2
- CEBPZ | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1187351184, COSV99135861; called by muse, mutect2, varscan2
- CEP170 | c.3799C>T p.R1267C | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs764258155, COSV100317279; called by muse, mutect2, varscan2
- CPAMD8 | c.3497C>T p.T1166I (on ENST00000651564; = p.T1119I on NM_015692.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs773863928, COSV101488633; called by muse, mutect2, varscan2
- CSH2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1446881129, COSV61080942; called by muse, mutect2, varscan2
- CSMD2 | c.9470G>A p.R3157H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs753503294, COSV53881918; called by muse, mutect2, varscan2
- DCC | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100503667; called by muse, mutect2, varscan2
- DENND2B | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777038380, COSV100567959; called by muse, mutect2, varscan2
- DEUP1 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99977756; called by muse, mutect2, varscan2
- DOCK7 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV99226361; called by muse, mutect2, varscan2
- DZIP1 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 115/164 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV61264154; called by muse, mutect2, varscan2
- ELOA2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV55298500, COSV55304671; called by muse, mutect2, varscan2
- EPB41L3 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 122/419 reads (29%) | catalogued as COSV100549375; called by muse, mutect2, varscan2
- FAM135B | c.3420C>A p.H1140Q | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52740540, COSV99428535; called by muse, mutect2, varscan2
- FBXO11 | c.1808G>A p.G603E (on ENST00000403359 / NM_001190274.2; = p.G519E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320120; called by muse, mutect2, varscan2
- FKTN | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.078); catalogued as COSV99795663; called by muse, mutect2, varscan2
- FLRT3 | c.138T>G p.D46E | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.338); catalogued as COSV99445755; called by muse, mutect2, varscan2
- FLT3 | c.614+1G>A p.X205_splice | Splice Site (SNP) | VAF 152/244 reads (62%) | catalogued as COSV99610484; called by muse, mutect2, varscan2
- FRMPD3 | c.3701C>G p.S1234C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.441); catalogued as COSV99347320; called by muse, varscan2
- FYCO1 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99946394; called by muse, mutect2, varscan2
- FYN | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99991637, COSV99992703; called by muse, mutect2, varscan2
- GPRC5A | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99185671; called by muse, mutect2, varscan2
- GRID2 | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99948093; called by muse, mutect2, varscan2
- HIVEP3 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770270422, COSV56017772; called by muse, mutect2, varscan2
- IQGAP3 | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs138382649; called by muse, mutect2, varscan2
- JRK | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554636031, COSV70629659; called by muse, mutect2, varscan2
- KCNC4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1374026643, COSV63925849; called by muse, mutect2, varscan2
- KCNK18 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs552800446, COSV57971233; called by muse, mutect2, varscan2
- KCTD8 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV100760236; called by muse, mutect2, varscan2
- LILRA2 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99254088; called by mutect2, varscan2
- LINGO3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1183531402, COSV101347290; called by muse, mutect2, varscan2
- LRRC1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV100906074; called by muse, mutect2, varscan2
- MAB21L1 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1396749667, COSV100085006; called by muse, mutect2, varscan2
- MACF1 | c.12764C>T p.T4255I (on ENST00000372915; = p.T2188I on NM_012090.5) | Missense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as rs969711467, COSV99247453; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MAT2B | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV99797017; called by muse, mutect2, varscan2
- MED13 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs377624680, COSV67263826; called by muse, mutect2, varscan2
- MMGT1 | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 19/113 reads (17%) | catalogued as COSV100018784; called by muse, mutect2, varscan2
- MUC5B | c.1259C>G p.P420R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV71594043; called by muse, mutect2, varscan2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV3 | c.6727T>C p.F2243L (on ENST00000397909 / NM_001024383.2; = p.F2221L on NM_014903.6) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99896722; called by muse, mutect2, varscan2
- NCL | c.1778A>G p.D593G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV100502513; called by muse, mutect2, varscan2
- NECTIN1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373047519, COSV99872749; called by muse, mutect2, varscan2
- NEMF | c.2485C>T p.L829F | Missense Mutation (SNP) | VAF 127/234 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100028205; called by muse, mutect2, varscan2
- NOTCH1 | c.5774A>G p.D1925G | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99492626; called by muse, mutect2, varscan2
- NSD1 | c.6143T>A p.I2048N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729924; called by muse, mutect2, varscan2
- OBSCN | c.8911C>T p.R2971W | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1015246918, COSV99485777; called by muse, mutect2
- OR10A3 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV100660349, COSV104415821; called by muse, mutect2, varscan2
- OSBPL7 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99137212; called by muse, mutect2, varscan2
- PADI1 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV100969321; called by muse, mutect2, varscan2
- PCDHB8 | c.2177G>A p.C726Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV50755919; called by muse, varscan2
- PDXDC1 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as COSV100363531; called by muse, mutect2
- PIAS1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759607395, COSV51034296; called by muse, mutect2, varscan2
- PIDD1 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs769334697, COSV57192316; called by muse, mutect2, varscan2
- PITX2 | c.745A>C p.S249R (on ENST00000354925 / NM_001204397.1; = p.S256R on NM_000325.6) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV60740304; called by muse, mutect2, varscan2
- PLEKHG2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs754187197, COSV52689510; called by muse, mutect2, varscan2
- POLDIP3 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99349424; called by muse, mutect2, varscan2
- PPFIA2 | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs564398471, COSV100334184, COSV61037503; called by muse, mutect2, varscan2
- PRAMEF17 | c.338G>C p.W113S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101068812; called by muse, mutect2, varscan2
- PRR12 | c.2459G>A p.R820Q (on ENST00000615927; = p.R1641Q on NM_020719.3) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs923300021, COSV69816765; called by muse, mutect2, varscan2
- RANBP9 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99163649; called by muse, mutect2, varscan2
- RECQL5 | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100512421; called by muse, mutect2, varscan2
- RFTN1 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100489861; called by muse, mutect2, varscan2
- RIMBP2 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs762190421, COSV55468028; called by muse, mutect2, varscan2
- RYR2 | c.12024C>A p.N4008K | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100773284, COSV63675738; called by muse, mutect2, varscan2
- SCN11A | c.2996T>A p.L999H | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV100180817, COSV100182891; called by muse, mutect2, varscan2
- SCN5A | c.6004G>A p.A2002T (on ENST00000333535 / NM_198056.3; = p.A2001T on NM_000335.5) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs771018427, COSV100351198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC23A | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV56971097; called by muse, mutect2, varscan2
- SFRP4 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs568754305, COSV71412719; called by muse, mutect2, varscan2
- SHROOM2 | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV101099172; called by muse, mutect2, varscan2
- SIPA1L2 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.368); catalogued as rs779216301, COSV99479954; called by muse, mutect2, varscan2
- SLC6A9 | c.1729C>T p.R577C (on ENST00000360584 / NM_201649.4; = p.R523C on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs773894277, COSV100746585; called by muse, mutect2, varscan2
- SORCS2 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs371719399; called by muse, mutect2, varscan2
- ST8SIA1 | c.403T>G p.L135V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); catalogued as COSV99683718; called by muse, mutect2, varscan2
- ST8SIA6 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV101112239; called by muse, mutect2, varscan2
- SUV39H1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs201867779, COSV100551884; called by muse, mutect2, varscan2
- SYNE1 | c.13105G>A p.E4369K (on ENST00000367255 / NM_182961.4; = p.E4298K on NM_033071.3) | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs777182389, COSV99583543; called by muse, mutect2, varscan2
- SYNE1 | c.2026T>G p.S676A (on ENST00000367255 / NM_182961.4; = p.S683A on NM_033071.3) | Missense Mutation (SNP) | VAF 111/323 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV99583547; called by muse, mutect2, varscan2
- SYT3 | c.1403-2A>G p.X468_splice | Splice Site (SNP) | VAF 36/97 reads (37%) | catalogued as COSV100144371; called by muse, mutect2, varscan2
- TAF1L | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs770879659, COSV54263482; called by muse, mutect2, varscan2
- TBXT | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99753037; called by muse, mutect2, varscan2
- THOC2 | c.4408A>T p.R1470* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV99834432; called by muse, mutect2, varscan2
- TLE2 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs764714978, COSV53578432; called by muse, mutect2, varscan2
- TMEM132B | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs775349963, COSV100170770; called by muse, mutect2, varscan2
- TMEM159 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV99238813; called by muse, mutect2, varscan2
- TRIM62 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370912607, COSV99358009; called by muse, mutect2, varscan2
- TSHZ3 | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99553102, COSV99553163; called by muse, mutect2, varscan2
- TUBGCP3 | c.2657A>C p.Y886S | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56184355; called by muse, mutect2
- VWA8 | c.5414C>T p.T1805M | Missense Mutation (SNP) | VAF 200/297 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761358108, COSV101023098; called by muse, mutect2, varscan2
- ZFHX3 | c.5401T>A p.Y1801N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51728879, COSV99215258; called by muse, mutect2, varscan2
- ZNF449 | c.830dup p.E278Rfs*23 | Frame Shift Ins (INS) | VAF 46/348 reads (13%) | catalogued as rs781874073; called by mutect2, varscan2
- ZNF518B | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as rs780296751, COSV58721842; called by muse, mutect2, varscan2
- ZNF654 | c.2146G>C p.D716H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV58804965; called by muse, mutect2, varscan2
- ZNF836 | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV59081230; called by muse, mutect2, varscan2
- ZNF98 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 161/508 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as rs775378052, COSV100757571, COSV63333852, COSV63334526; called by muse, mutect2, varscan2
- GOLGA1 | c.323del p.E108Gfs*21 | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, pindel, varscan2
- NXPE4 | c.749_753del p.P250Rfs*9 | Frame Shift Del (DEL) | VAF 39/111 reads (35%) | called by mutect2, pindel, varscan2
- SYNRG | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- SYNRG | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TP53 | c.430_435dup p.Q144_L145dup | In Frame Ins (INS) | VAF 22/46 reads (48%) | called by mutect2, varscan2
- TRERF1 | c.2557_2560del p.F853Rfs*6 | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.1496_1502delinsCATT p.D499_P501delinsAF | In Frame Del (DEL) | VAF 14/111 reads (13%) | called by pindel, varscan2*
- AP2A1 | c.2136C>T p.P712= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs954062156, COSV100571277; called by muse, mutect2, varscan2
- ATP1A1 | c.717G>A p.T239= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs561066145, COSV55192971, COSV99814869; called by muse, mutect2, varscan2
- BPIFB6 | c.1092C>T p.V364= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV100848504, COSV100848563; called by muse, mutect2
- BPNT1 | c.774G>A p.V258= | Silent (SNP) | VAF 83/266 reads (31%) | catalogued as COSV100435890; called by muse, mutect2, varscan2
- CHD5 | c.3294C>A p.L1098= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99315453; called by muse, mutect2, varscan2
- COL4A2 | c.3972C>A p.T1324= | Silent (SNP) | VAF 112/182 reads (62%) | catalogued as COSV64625117; called by muse, mutect2, varscan2
- DGKB | c.900G>A p.K300= | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV99344221; called by muse, mutect2, varscan2
- DIP2C | c.2511C>T p.D837= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs199725116, COSV99794095; called by muse, mutect2, varscan2
- DNAH7 | c.8583C>T p.D2861= | Silent (SNP) | VAF 61/195 reads (31%) | catalogued as COSV100418129; called by muse, mutect2, varscan2
- DUOX2 | c.1731C>T p.D577= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as rs781082019, COSV101199813, COSV66533406; ClinVar: likely benign; called by muse, mutect2, varscan2
- E2F3 | c.27G>A p.L9= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100685892, COSV100686363; called by muse, mutect2, varscan2
- EPHB1 | c.2616G>A p.A872= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as rs760099232, COSV67659427; called by muse, mutect2, varscan2
- FAM78A | c.780C>T p.N260= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs573768553, COSV55992627; called by muse, mutect2, varscan2
- FAT4 | c.7536T>A p.S2512= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV100630556; called by muse, mutect2, varscan2
- FREM2 | c.336C>T p.N112= | Silent (SNP) | VAF 68/99 reads (69%) | catalogued as rs750106928, COSV54842264; called by muse, mutect2, varscan2
- GGNBP2 | c.495C>T p.H165= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- GHRH | c.72T>C p.P24= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV99411149, COSV99411254; called by muse, mutect2, varscan2
- GJC1 | c.402C>T p.N134= | Silent (SNP) | VAF 64/305 reads (21%) | catalogued as rs767121932, COSV57911418; called by muse, mutect2, varscan2
- GTDC1 | c.717A>C p.S239= | Silent (SNP) | VAF 73/237 reads (31%) | catalogued as COSV99602191; called by muse, mutect2, varscan2
- IGKV2D-29 | c.114G>A p.P38= | Silent (SNP) | VAF 63/186 reads (34%) | catalogued as rs779737654, COSV101534403; called by muse, mutect2, varscan2
- IGLV9-49 | c.202C>A p.R68= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- KCNA3 | c.282G>A p.P94= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100871330; called by muse, mutect2, varscan2
- KCNK2 | c.984C>T p.H328= (on ENST00000444842 / NM_001017425.3; = p.H313= on NM_014217.4) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs773024551, COSV101222390; called by muse, mutect2, varscan2
- KCNN3 | c.351C>T p.T117= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs781367114, COSV99679496; called by muse, varscan2
- LLGL1 | c.3180C>T p.A1060= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57496378; called by muse, mutect2, varscan2
- MBL2 | c.126C>T p.G42= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs915526846, COSV100906437; called by muse, mutect2, varscan2
- MYDGF | c.66G>A p.G22= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs749618925, COSV99501767; called by muse, mutect2, varscan2
- NCKAP5 | c.5151A>G p.T1717= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100494790; called by muse, mutect2, varscan2
- OGFOD3 | c.663G>A p.T221= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs781653720, COSV100234592; called by muse, varscan2
- OR2G2 | c.171G>A p.K57= | Silent (SNP) | VAF 145/439 reads (33%) | catalogued as COSV100190060, COSV60740676; called by muse, mutect2, varscan2
- PCDHA11 | c.1572C>T p.H524= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs1554164570, COSV56536366; called by muse, mutect2, varscan2
- PCK2 | c.1689G>A p.E563= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs1193364826, COSV99394729; called by muse, mutect2, varscan2
- PHACTR4 | c.1563C>T p.P521= (on ENST00000373839 / NM_001350159.2; = p.P531= on NM_023923.4) | Silent (SNP) | VAF 99/296 reads (33%) | catalogued as rs998235300, COSV100868511; called by muse, mutect2, varscan2
- PRRX2 | c.420C>T p.R140= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs537836904, COSV100991220; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RXFP3 | c.174C>T p.D58= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs539921901, COSV100347854, COSV57508395; called by muse, mutect2, varscan2
- SCML2 | c.1320C>T p.N440= | Silent (SNP) | VAF 104/389 reads (27%) | catalogued as COSV99319604; called by muse, mutect2, varscan2
- SLC25A42 | c.882G>A p.K294= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV100588262; called by muse, mutect2, varscan2
- SOGA1 | c.975G>A p.A325= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as rs753201709, COSV52912218; called by muse, mutect2, varscan2
- SPON1 | c.765C>T p.G255= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs782780710, COSV59957846; called by muse, mutect2, varscan2
- TLE4 | c.1996C>T p.L666= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as COSV54626754, COSV99513281; called by muse, mutect2, varscan2
- TLR7 | c.1599T>C p.L533= | Silent (SNP) | VAF 93/218 reads (43%) | catalogued as COSV101028200; called by muse, mutect2, varscan2
- UBR7 | c.438C>T p.D146= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs137967567; called by muse, mutect2, varscan2
- ZXDA | c.177C>T p.R59= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100699502; called by muse, mutect2, varscan2
- MTAP | c.813+2556G>A | Intron (SNP) | VAF 70/266 reads (26%) | catalogued as COSV101205529; called by muse, mutect2, varscan2
- OCLNP1 | n.519A>T | RNA (SNP) | VAF 22/923 reads (2%) | called by muse, mutect2
- OSGIN1 | n.1833G>A | RNA (SNP) | VAF 67/191 reads (35%) | catalogued as rs751178429, COSV59419337; called by muse, mutect2, varscan2
